Somatic mutation profile of tumor specimen 0DC62Z from CCDI case PBBILR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.3 years (833 days).
Specimen 0DC62Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0ebef2f-5106-4dcc-a8c9-0b5851883a91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DC632 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7f45e8b-4b31-41bf-a64f-842f9185710b

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EZHIP | c.402G>T p.E134D | Missense Mutation (SNP) | VAF 167/435 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.351); catalogued as rs1451878384; called by muse, varscan2
- WWC2 | c.1408T>A p.Y470N | Missense Mutation (SNP) | VAF 230/521 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66715502; called by muse, varscan2
